Somatic mutation profile of tumor specimen db3f5ad9-d14d-4126-a3e7-d80faa (aliquot db3f5ad9-d14d-4126-a3e7-d80faa_D6_1) from CPTAC case 14CO005, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen db3f5ad9-d14d-4126-a3e7-d80faa: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a7d4965d-1049-4fbe-a51d-35362dc6fac1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 2007507a-455c-4a72-bf89-9ee8c2 (Blood Derived Normal), aliquot 2007507a-455c-4a72-bf89-9ee8c2_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b3df3f89-9a1f-413b-aadd-9a45569ca7ba

The open-access MAF lists 120 somatic variants for this specimen: 80 protein-altering or splice-affecting, 28 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 28, Intron 7, Nonsense Mutation 6, RNA 3, Frame Shift Ins 1, 5'Flank 1, IGR 1, Splice Region 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 89/361 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ADCY8 | c.3025C>T p.R1009C | Missense Mutation (SNP) | VAF 21/273 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1475267602, COSV53905124; called by muse, mutect2
- ARHGAP45 | c.1550C>T p.T517M | Missense Mutation (SNP) | VAF 29/245 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1349194001; called by muse, mutect2, varscan2
- ASPM | c.4999C>T p.R1667C | Missense Mutation (SNP) | VAF 32/341 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755281471; called by muse, mutect2
- BCAR3 | c.2353C>T p.R785* | Nonsense Mutation (SNP) | VAF 14/120 reads (12%) | catalogued as rs749096646, COSV53073481; called by muse, mutect2, varscan2
- CCT6B | c.650G>A p.R217H | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as rs749788960, COSV58489848; called by muse, mutect2, varscan2
- CD22 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 72/280 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.735); catalogued as rs745645352, COSV50050278; called by muse, mutect2, varscan2
- CDK14 | c.1273C>T p.R425W (on ENST00000380050 / NM_001287135.2; = p.R407W on NM_012395.3) | Missense Mutation (SNP) | VAF 36/333 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs140184613, COSV56040635; called by muse, varscan2
- CNNM1 | c.2488G>A p.A830T | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs779616573, COSV100763843; called by muse, mutect2, varscan2
- COL11A1 | c.4427C>G p.P1476R | Missense Mutation (SNP) | VAF 43/253 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV62191733; called by muse, mutect2, varscan2
- CRYGN | c.317C>T p.T106M | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT tolerated (0.25); PolyPhen benign (0.369); catalogued as rs374865002; called by muse, mutect2, varscan2
- CXADR | c.694C>T p.P232S | Missense Mutation (SNP) | VAF 42/148 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.343); catalogued as rs373959241; called by muse, mutect2, varscan2
- DNAJB4 | c.718C>T p.H240Y | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV66131996; called by muse, mutect2, varscan2
- ECHDC3 | c.460G>A p.G154S | Missense Mutation (SNP) | VAF 104/383 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375815859; called by muse, varscan2
- ELFN2 | c.1792C>T p.R598W | Missense Mutation (SNP) | VAF 34/118 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs747077460, COSV68745648; called by muse, mutect2, varscan2
- FAT4 | c.5468C>T p.S1823L | Missense Mutation (SNP) | VAF 50/306 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs758045956, COSV100628060, COSV58676301; called by muse, mutect2, varscan2
- FGF5 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 63/291 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs888543317; called by muse, mutect2, varscan2
- FSIP2 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 24/86 reads (28%) | SIFT tolerated (0.21); catalogued as rs906304167; called by muse, mutect2, varscan2
- GAA | c.545C>T p.T182M | Missense Mutation (SNP) | VAF 90/407 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as rs200524747; called by muse, mutect2, varscan2
- GABRE | c.1153C>T p.R385C | Missense Mutation (SNP) | VAF 38/400 reads (10%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.877); catalogued as rs779955932, COSV100944278; called by muse, mutect2
- GPR141 | c.666G>A p.W222* | Nonsense Mutation (SNP) | VAF 70/330 reads (21%) | catalogued as rs1158816682, COSV57731561; called by mutect2, varscan2
- GRM8 | c.2300C>T p.A767V | Missense Mutation (SNP) | VAF 52/242 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1447351317; called by muse, mutect2, varscan2
- HAS1 | c.1687G>A p.V563M | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.41); catalogued as rs754136062, COSV55787766; called by muse, mutect2, varscan2
- HCN4 | c.995G>A p.R332Q | Missense Mutation (SNP) | VAF 49/553 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.06); catalogued as rs368164073, COSV56085738; ClinVar: uncertain significance; called by muse, mutect2
- IGFN1 | c.947C>T p.A316V | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.017); catalogued as rs781592987, COSV55165623; called by muse, mutect2, varscan2
- ITPKB | c.217G>A p.G73R | Missense Mutation (SNP) | VAF 53/157 reads (34%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.521); catalogued as rs766692739; called by muse, mutect2, varscan2
- KCNA5 | c.1486G>A p.V496M | Missense Mutation (SNP) | VAF 68/521 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs757749649, COSV52905561; called by muse, mutect2, varscan2
- KCNQ5 | c.1144G>A p.A382T | Missense Mutation (SNP) | VAF 51/139 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1190788387, COSV59664800; called by muse, varscan2
- KCNV2 | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 131/563 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); catalogued as rs745988476, COSV66057646; called by muse, mutect2, varscan2
- MAP3K10 | c.1307G>A p.R436Q | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV53420309; called by muse, mutect2, varscan2
- MAP4K2 | c.1685G>A p.R562Q | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.988); catalogued as rs565633083, COSV53646326; called by muse, mutect2
- MORF4L2 | c.70C>A p.P24T | Missense Mutation (SNP) | VAF 24/197 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.019); catalogued as rs1192153079, COSV100846395; called by muse, mutect2, varscan2
- MYO18B | c.4400G>A p.R1467Q | Missense Mutation (SNP) | VAF 39/194 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs755347673; called by muse, mutect2, varscan2
- OLFML2B | c.412C>T p.R138W | Missense Mutation (SNP) | VAF 19/349 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs149125065; called by muse, mutect2
- PCDHGB2 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 128/750 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV53930536; called by mutect2, varscan2
- PDIA4 | c.1108C>T p.R370W | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs944124241, COSV99618513; called by muse, mutect2, varscan2
- PPFIA3 | c.3437C>T p.S1146L | Missense Mutation (SNP) | VAF 60/221 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.917); catalogued as COSV53255221, COSV99417994; called by muse, mutect2, varscan2
- PPP1R3A | c.1867G>A p.G623R | Missense Mutation (SNP) | VAF 249/813 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1376114512; called by muse, mutect2, varscan2
- RAI1 | c.1762G>A p.V588M | Missense Mutation (SNP) | VAF 44/555 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as rs546791674; called by muse, mutect2
- SMAD2 | c.899A>G p.D300G | Missense Mutation (SNP) | VAF 47/340 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV50994444, COSV51001171, COSV51014150; called by muse, mutect2, varscan2
- TFAP4 | c.458G>A p.R153Q | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.953); catalogued as COSV99200047; called by muse, mutect2, varscan2
- TJAP1 | c.559C>T p.R187* (on ENST00000372445 / NM_001146016.1; = p.R177* on NM_080604.3) | Nonsense Mutation (SNP) | VAF 131/457 reads (29%) | catalogued as rs1382298758, COSV52503251; called by muse, mutect2, varscan2
- TLL1 | c.1888A>C p.T630P | Missense Mutation (SNP) | VAF 10/216 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.02); catalogued as COSV50284389; called by muse, mutect2
- TM9SF4 | c.652+1G>T p.X218_splice | Splice Site (SNP) | VAF 94/335 reads (28%) | catalogued as rs995363387; called by muse, mutect2, varscan2
- VAT1L | c.94G>A p.G32S | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs976842729; called by muse, mutect2
- WNK3 | c.1517G>A p.R506H | Missense Mutation (SNP) | VAF 48/289 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.015); catalogued as rs782571046, COSV63612108; called by muse, mutect2, varscan2
- ZDBF2 | c.872G>A p.R291H | Missense Mutation (SNP) | VAF 28/132 reads (21%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as rs1249887867; called by muse, mutect2, varscan2
- ZNF114 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 50/201 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.206); catalogued as rs764656612, COSV59945543; called by muse, mutect2, varscan2
- ZNF208 | c.226+7G>A | Splice Region (SNP) | VAF 18/68 reads (26%) | catalogued as rs548920482; called by muse, mutect2, varscan2
- ZSWIM3 | c.184C>T p.R62W | Missense Mutation (SNP) | VAF 74/218 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as rs543006815, COSV54845845; called by muse, mutect2, varscan2
- APC | c.3897_3903dup p.L1302* | Frame Shift Ins (INS) | VAF 204/470 reads (43%) | called by mutect2, varscan2
- APOL1 | c.1084G>A p.G362R | Missense Mutation (SNP) | VAF 11/268 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- C2CD4C | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 45/120 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- CLVS1 | c.217G>T p.D73Y | Missense Mutation (SNP) | VAF 111/481 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- CPA3 | c.1213G>A p.V405I | Missense Mutation (SNP) | VAF 15/127 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- DNAH1 | c.5637G>A p.M1879I | Missense Mutation (SNP) | VAF 79/272 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- EFCAB5 | c.1334C>T p.T445I | Missense Mutation (SNP) | VAF 14/118 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- IGFBP4 | c.360G>C p.E120D | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2
- INTS5 | c.2295G>C p.Q765H | Missense Mutation (SNP) | VAF 41/434 reads (9%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2
- KIF2B | c.1201C>A p.L401M | Missense Mutation (SNP) | VAF 37/321 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.688); called by muse, mutect2, varscan2
- MCF2L | c.1840A>G p.S614G (on ENST00000375608; = p.S582G on NM_024979.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 59/602 reads (10%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2
- MEGF10 | c.1439T>C p.V480A | Missense Mutation (SNP) | VAF 30/187 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- NONO | c.1250C>A p.A417D | Missense Mutation (SNP) | VAF 10/206 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.031); called by muse, mutect2
- NPFFR1 | c.1168A>G p.S390G | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- OVCH1 | c.512T>C p.I171T | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.69); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- PIN4 | c.350G>A p.G117E (on ENST00000664196; = p.G92E on NM_006223.4) | Missense Mutation (SNP) | VAF 15/208 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.988); called by muse, mutect2
- PREX1 | c.2662G>T p.E888* | Nonsense Mutation (SNP) | VAF 20/198 reads (10%) | called by muse, mutect2
- PRKCQ | c.1753G>A p.E585K | Missense Mutation (SNP) | VAF 13/180 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- RELL1 | c.721G>T p.E241* | Nonsense Mutation (SNP) | VAF 67/168 reads (40%) | called by muse, mutect2, varscan2
- SCN11A | c.3236A>C p.H1079P | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- SLC22A2 | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- SMAD3 | c.1158A>T p.R386S | Missense Mutation (SNP) | VAF 24/314 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); called by muse, mutect2
- TBC1D3F | c.688G>A p.G230R | Missense Mutation (SNP) | VAF 24/96 reads (25%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by mutect2, varscan2
- TOPBP1 | c.1529G>A p.R510K | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.93); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TTC23L | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- YBX2 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 28/218 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZKSCAN8 | c.1711G>T p.E571* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- ZNF334 | c.865G>A p.G289R | Missense Mutation (SNP) | VAF 53/214 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF599 | c.397G>T p.G133W | Missense Mutation (SNP) | VAF 26/344 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); called by muse, mutect2
- ZNF729 | c.1455G>C p.E485D | Missense Mutation (SNP) | VAF 69/425 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- AVPR1A | c.132C>T p.D44= | Silent (SNP) | VAF 66/541 reads (12%) | catalogued as rs758324485, COSV54546541; called by muse, mutect2, varscan2
- C11orf1 | c.246T>C p.N82= | Silent (SNP) | VAF 31/106 reads (29%) | catalogued as rs1039647964; called by muse, mutect2, varscan2
- CGB7 | c.360C>T p.C120= | Silent (SNP) | VAF 85/520 reads (16%) | catalogued as rs1375732554, COSV62281977; called by muse, mutect2, varscan2
- CLIP2 | c.366C>T p.G122= | Silent (SNP) | VAF 48/596 reads (8%) | catalogued as rs2301972, COSV56277378; called by muse, mutect2
- FAM90A10P | c.477G>A p.P159= | Silent (SNP) | VAF 61/117 reads (52%) | catalogued as rs1421201050; called by muse, mutect2, varscan2
- FBN3 | c.4839C>T p.S1613= | Silent (SNP) | VAF 12/123 reads (10%) | catalogued as rs199833606, COSV99560335; called by muse, mutect2, varscan2
- FLNA | c.3612G>A p.P1204= | Silent (SNP) | VAF 74/892 reads (8%) | catalogued as rs782273962; ClinVar: likely benign; called by muse, mutect2
- HCFC1 | c.3342G>A p.T1114= | Silent (SNP) | VAF 47/507 reads (9%) | catalogued as rs868910589, COSV60076034; ClinVar: likely benign; called by muse, mutect2
- KIF6 | c.51G>C p.R17= | Silent (SNP) | VAF 48/176 reads (27%) | catalogued as COSV99761239; called by muse, mutect2, varscan2
- KIF9 | c.210T>C p.Y70= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs754348283; called by muse, mutect2, varscan2
- KIRREL2 | c.1476C>T p.G492= | Silent (SNP) | VAF 17/232 reads (7%) | catalogued as rs769114699; called by muse, mutect2
- KLHL40 | c.198G>A p.P66= | Silent (SNP) | VAF 66/515 reads (13%) | catalogued as COSV55132516; called by muse, mutect2, varscan2
- KRTAP13-3 | c.153T>C p.S51= | Silent (SNP) | VAF 22/449 reads (5%) | called by muse, mutect2
- LRRN1 | c.1938G>A p.A646= | Silent (SNP) | VAF 40/281 reads (14%) | catalogued as rs372935124, COSV60012312; called by muse, mutect2, varscan2
- MIER3 | c.1203C>T p.T401= (on ENST00000381199 / NM_001297599.2; = p.T400= on NM_152622.4) | Silent (SNP) | VAF 73/230 reads (32%) | called by mutect2, varscan2
- MOCS3 | c.546C>T p.N182= | Silent (SNP) | VAF 32/511 reads (6%) | called by muse, mutect2
- MPP1 | c.1242G>A p.Q414= | Silent (SNP) | VAF 14/166 reads (8%) | called by muse, mutect2
- MUC20 | c.2085C>T p.H695= | Silent (SNP) | VAF 45/277 reads (16%) | catalogued as rs536626783, COSV57853066; called by muse, mutect2, varscan2
- NAA16 | c.90C>T p.L30= | Silent (SNP) | VAF 64/176 reads (36%) | catalogued as COSV65063970; called by muse, mutect2, varscan2
- NOS1 | c.1656G>A p.R552= | Silent (SNP) | VAF 35/127 reads (28%) | called by muse, mutect2, varscan2
- NT5C1B | c.870C>T p.Y290= (on ENST00000359846 / NM_001199086.2; = p.Y230= on NM_033253.4) | Silent (SNP) | VAF 47/294 reads (16%) | catalogued as rs746909085, COSV58394165; called by muse, varscan2
- PCDHGA2 | c.1722C>T p.G574= | Silent (SNP) | VAF 486/924 reads (53%) | catalogued as COSV53912616; called by muse, mutect2, varscan2
- PIANP | c.67C>T p.L23= | Silent (SNP) | VAF 10/85 reads (12%) | called by muse, mutect2, varscan2
- PPFIA4 | c.3528C>T p.Y1176= (on ENST00000447715; = p.Y1177= on NM_001304331.2 and 1 other RefSeq transcript) | Silent (SNP) | VAF 35/255 reads (14%) | called by muse, mutect2, varscan2
- SERPINE3 | c.798A>G p.K266= | Silent (SNP) | VAF 133/392 reads (34%) | called by muse, mutect2, varscan2
- SMG6 | c.1359C>T p.R453= | Silent (SNP) | VAF 37/248 reads (15%) | called by muse, mutect2, varscan2
- SPATA17 | c.207C>T p.F69= | Silent (SNP) | VAF 5/72 reads (7%) | called by muse, mutect2
- TEX15 | c.7236G>A p.S2412= (on ENST00000256246; = p.S2795= on NM_001350162.2) | Silent (SNP) | VAF 10/73 reads (14%) | catalogued as rs371955113; called by muse, mutect2, varscan2
- AC024651.2 | chr15:97874282 G>A | 5'Flank (SNP) | VAF 35/163 reads (21%) | catalogued as rs1256948100; called by mutect2, varscan2
- AC244517.10 | c.36-9285C>T | Intron (SNP) | VAF 93/912 reads (10%) | catalogued as COSV73144966; called by muse, mutect2, varscan2
- ACER3 | c.103+7091C>T | Intron (SNP) | VAF 48/159 reads (30%) | catalogued as rs1205772725; called by muse, mutect2, varscan2
- AL627230.3 | c.75+233T>A | Intron (SNP) | VAF 141/892 reads (16%) | called by muse, varscan2
- GPC1 | c.167-8000G>T | Intron (SNP) | VAF 66/257 reads (26%) | catalogued as rs1442110473; called by muse, mutect2, varscan2
- GSDME | c.404+16T>A | Intron (SNP) | VAF 79/324 reads (24%) | called by muse, mutect2, varscan2
- IRX5 | c.250-398C>G | Intron (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- LINC00269 | n.421G>A | RNA (SNP) | VAF 23/150 reads (15%) | catalogued as rs1039947440; called by muse, mutect2, varscan2
- LINC01587 | n.371C>A | RNA (SNP) | VAF 10/67 reads (15%) | called by muse, mutect2, varscan2
- SLC6A10P | n.3649G>A | RNA (SNP) | VAF 57/508 reads (11%) | catalogued as rs1174086803; called by muse, mutect2, varscan2
- SPP1 | c.93+753_93+754insAAA | Intron (INS) | VAF 7/82 reads (9%) | called by mutect2, pindel
- Unknown | chr16:27288818 C>A | IGR (SNP) | VAF 16/141 reads (11%) | called by muse, mutect2, varscan2
